CCDI case PBCNIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/5ddb8e43-525a-45aa-9471-c78cad957ffa

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.3 years (1,203 days).

Biospecimens (3 samples)
- Sample 0DWHZ5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWI1V: Tissue type: Tumor; Specimen type: Solid Tissue.
